Surgical pathology report (de-identified scan), TCGA case TCGA-F9-A7VF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Asterand, specimen TCGA-F9-A7VF-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: A. "Fat over mass." A 6.5 x 5.5 x 2.0 cm aggregate of unremarkable fatty fragments.
B. "Left kidney ." A 186 gram, 13.5 x 7.5 x 3.1 cm kidney with previously stripped perinephric fat and capsule. The renal artery, vein and ureter at the margin are unremarkable. A well circumscribed slightly necrotic 3.5 x 2.5 x 2.5 cm mass in the lower pole is grossly confined within the kidney. No extension into the small amount of perinephric fat is identified. The remainder of the kidney to include the renal pelvis is grossly unremarkable. A separate 6.5 x 4.5 cm aggregate of perinephric fat is received and is unremarkable.

Microscopic Description: Procedure type: Radical nephrectomy

Histologic grade (Fuhrman): Mostly grade 2, focally (10-20%) grade 3.

Sarcomatoid features: Absent

Tumor size: 3.5 cm

Extent: Limited to kidney.

Adrenal Gland: Not present in specimen.

Angiolymphatic invasion: Absent

Margins: All margins free of tumor

Fat over mass (A): Benign adipose tissue.

Lymph nodes: None present

Pathologic stage: pT1a Nx Mx

Non-neoplastic kidney: Atherosclerosis, mild glomerulosclerosis and scarring.

Focal papillary adenoma (1 mm) away from tumor mass, Immunostains were previously performed on the biopsy and consistent with a papillary RCC. Neoplasm has relatively higher Fuhrman nuclear grade than typical papillary renal cell carcinoma (probably grade 3), however morphology is compatible. Immunostains for cytokeratin 7, pancytokeratin, p504S and PAX-8 were performed and all four stains are positive. This is consistent with a papillary-type renal cell carcinoma.

Diagnosis Details: KIDNEY (LEFT, B): RENAL CELL CARCINOMA, PAPILLARY TYPE (TYPE I)

Comments:

Formatted Path Reports: KIDNEY TISSUE CHECKLIST

Specimen type: Nephrectomy

ILD-0-3

Carcinoma, papillary renal cell
8260/3

Site @ Kidney NOS
C64.9

4/10/13

[page 2 of 2]
Tumor site: Kidney

Tumor size: 3.5 x 2.5 x 2.5 cm

Focality: Not specified

Histologic type: Papillary renal cell carcinoma

Histologic grade: Not specified

Tumor extent: Limited to kidney

Lymph nodes: Not specified

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left

Reviewed Initials	9/24/13	

Source: NCI Genomic Data Commons file 2febf19c-4ae4-41fc-9417-9f01937b3b61 (TCGA-F9-A7VF.F8C9C91D-6AED-43EF-BC8F-0481A311706B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).